CCDI case PBBYEE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/dacb3471-e165-46ee-be12-d98a70f4c71e

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.6 years (5,327 days).

Biospecimens (3 samples)
- Sample 0DKRCC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKRCO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKRD1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
